Somatic mutation profile of tumor specimen PCProject_0608_T2_WES (aliquot PCProject_0608_T2_WES_1) from CMI case PCProject_0608, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 61.1 years (22,322 days).
Specimen PCProject_0608_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 304f24c9-c94a-40ed-a000-07c45fabf884.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0608_SALIVA (DNA), aliquot PCProject_0608_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d28bdaf1-0634-4a31-870b-4c36e393222a

The open-access MAF lists 23 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, Intron 2, Frame Shift Del 2, 5'UTR 1, RNA 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF2 | c.365C>T p.S122L (on ENST00000361247 / NM_001162383.2; = p.S95L on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58113801; called by muse, mutect2, varscan2
- KDM4A | c.503T>C p.I168T | Missense Mutation (SNP) | VAF 17/182 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs763662886, COSV64959654; called by muse, mutect2, varscan2
- MET | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 44/223 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs986139438; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OOEP | c.34C>T p.R12W | Missense Mutation (SNP) | VAF 10/233 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs891507935, COSV64859558; called by muse, mutect2
- PHLDB1 | c.1423C>T p.R475W | Missense Mutation (SNP) | VAF 46/218 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as rs1187861732, COSV100616896, COSV61877947; called by muse, mutect2, varscan2
- PLK2 | c.19A>G p.I7V | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.011); catalogued as rs757948197, COSV57107657; called by muse, mutect2
- POLE | c.2299G>A p.E767K | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.721); catalogued as rs1565964543, COSV57675985; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRU | c.4124G>A p.R1375H | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374427295, COSV60524434; called by muse, mutect2, varscan2
- CD300C | c.640dup p.S214Kfs*9 | Frame Shift Ins (INS) | VAF 41/241 reads (17%) | called by mutect2, pindel, varscan2
- DDA1 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 47/317 reads (15%) | called by muse, mutect2, varscan2
- EDEM3 | c.2225G>T p.S742I | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- NPLOC4 | c.55_57delinsCC p.T19Pfs*12 | Frame Shift Del (DEL) | VAF 33/221 reads (15%) | called by pindel, varscan2*
- SCAF4 | c.2496_2497del p.G833Sfs*84 | Frame Shift Del (DEL) | VAF 93/456 reads (20%) | called by mutect2, pindel*, varscan2*
- TBC1D16 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 76/341 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- DOCK10 | c.600C>T p.T200= | Silent (SNP) | VAF 33/178 reads (19%) | catalogued as rs769151809, COSV51423896; called by muse, mutect2, varscan2
- IL27RA | c.654C>T p.G218= | Silent (SNP) | VAF 45/157 reads (29%) | catalogued as rs202125422; called by muse, mutect2, varscan2
- KMT2A | c.2985A>G p.S995= | Silent (SNP) | VAF 33/207 reads (16%) | called by muse, mutect2, varscan2
- OR10A4 | c.510T>C p.C170= | Silent (SNP) | VAF 52/282 reads (18%) | called by muse, mutect2, varscan2
- TBCA | c.19A>C p.R7= | Silent (SNP) | VAF 83/552 reads (15%) | called by muse, mutect2, varscan2
- GFRA3 | c.-18C>T | 5'UTR (SNP) | VAF 8/126 reads (6%) | catalogued as rs1377062225; called by muse, mutect2
- LINC02412 | n.838_846del | RNA (DEL) | VAF 32/308 reads (10%) | called by mutect2, pindel, varscan2
- NBAS | c.1084-5067T>C | Intron (SNP) | VAF 9/30 reads (30%) | catalogued as rs1429179063; called by mutect2, varscan2
- NBAS | c.1084-5071_1084-5070del | Intron (DEL) | VAF 8/28 reads (29%) | catalogued as rs1169722994; called by mutect2, varscan2
